Somatic mutation profile of tumor specimen TCGA-66-2785-01A (aliquot TCGA-66-2785-01A-01D-1522-08) from TCGA case TCGA-66-2785, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.1 years (23,772 days).
Specimen TCGA-66-2785-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07a0560e-31e0-4e7b-9178-ff070f363877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2785-11A (Solid Tissue Normal), aliquot TCGA-66-2785-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f8fda36-32d9-4ac1-b088-1839271bf66d

The open-access MAF lists 1,182 somatic variants for this specimen: 917 protein-altering or splice-affecting, 242 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 801, Silent 242, Nonsense Mutation 71, Splice Site 14, Frame Shift Del 12, Intron 10, RNA 8, Splice Region 8, Nonstop Mutation 4, Translation Start Site 4, 5'UTR 3, 3'UTR 2.

Variants (750 of 1,182; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- LDLR | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 110/934 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs879254511, CM132108, COSV52943164; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCA9 | c.3485T>C p.L1162P | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV60624520; called by muse, mutect2, varscan2
- ABCB1 | c.3523C>T p.Q1175* | Nonsense Mutation (SNP) | VAF 21/193 reads (11%) | catalogued as COSV55950647; called by muse, mutect2, varscan2
- ABCB1 | c.1555-1G>A p.X519_splice | Splice Site (SNP) | VAF 24/204 reads (12%) | catalogued as COSV55950657, COSV99711894; called by muse, mutect2, varscan2
- ABCB5 | c.3033T>A p.C1011* (on ENST00000404938 / NM_001163941.2; = p.C566* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as COSV51709144; called by muse, mutect2, varscan2
- ABCB7 | c.1762C>T p.H588Y (on ENST00000373394 / NM_001271696.3; = p.H589Y on NM_004299.6) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV53719724, COSV53723438; called by muse, mutect2, varscan2
- ABCC1 | c.2919C>A p.F973L | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV60685428; called by muse, mutect2, varscan2
- ABCC10 | c.1060C>A p.Q354K (on ENST00000372530 / NM_001198934.2; = p.Q311K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.874); catalogued as COSV55087429, COSV55092062; called by muse, mutect2
- ABCC10 | c.4204-1G>C p.X1402_splice (on ENST00000372530 / NM_001198934.2; = p.X1374_splice on NM_033450.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/179 reads (7%) | catalogued as COSV55087443; called by muse, mutect2
- ABI3BP | c.2858C>G p.S953* | Nonsense Mutation (SNP) | VAF 27/154 reads (18%) | catalogued as COSV52535565; called by muse, mutect2, varscan2
- ABI3BP | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV52535584; called by muse, mutect2, varscan2
- AC006059.2 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.17); catalogued as rs140850059, COSV59606825; called by muse, mutect2, varscan2
- AC013489.1 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51551210, COSV51554431; called by muse, mutect2, varscan2
- ACAD10 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV58156531; called by muse, mutect2
- ACSM1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs549226687, COSV54635480; called by muse, mutect2, varscan2
- ACTBL2 | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV70661254; called by muse, mutect2, varscan2
- ACTL8 | c.687G>C p.Q229H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); catalogued as COSV100958771, COSV64861356; called by muse, mutect2, varscan2
- ACVR2A | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 33/264 reads (13%) | catalogued as COSV54022060; called by muse, mutect2, varscan2
- ADAM22 | c.1511G>C p.R504P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55976405; called by muse, mutect2, varscan2
- ADAMTS3 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54390949; called by muse, mutect2, varscan2
- ADAMTS5 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53178891; called by muse, mutect2, varscan2
- ADAMTSL4 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.069); catalogued as rs776367276, COSV54999520; called by mutect2, varscan2
- ADAT1 | c.1125G>C p.Q375H | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766979964, COSV57186397; called by muse, varscan2
- ADAT1 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57186409; called by muse, varscan2
- ADCY2 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs149172094; called by muse, mutect2, varscan2
- ADCY7 | c.2971G>T p.G991C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54266637; called by muse, mutect2, varscan2
- ADCY9 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV53575002; called by muse, mutect2, varscan2
- ADGRB3 | c.1763G>C p.R588P | Missense Mutation (SNP) | VAF 67/672 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65394023; called by muse, mutect2, varscan2
- ADGRL1 | c.3706G>C p.A1236P (on ENST00000340736 / NM_001008701.3; = p.A1231P on NM_014921.5) | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV61564633; called by muse, mutect2, varscan2
- ADIPOR2 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 174/907 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63946254; called by muse, mutect2, varscan2
- AFAP1L1 | c.1158G>C p.M386I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57045106, COSV57048059; called by muse, mutect2, varscan2
- AFP | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as COSV56925125; called by muse, mutect2, varscan2
- AGAP2 | c.1406C>T p.S469L (on ENST00000547588 / NM_001122772.2; = p.S133L on NM_014770.4) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV57728029; called by muse, mutect2, varscan2
- AGBL1 | c.1562C>A p.T521N | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101223172, COSV66857509; called by muse, mutect2, varscan2
- AHNAK | c.13219C>G p.L4407V | Missense Mutation (SNP) | VAF 70/505 reads (14%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as COSV57212742; called by muse, mutect2, varscan2
- AHNAK2 | c.5851C>G p.L1951V | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV60914846; called by muse, mutect2, varscan2
- AHNAK2 | c.954G>C p.Q318H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60914853; called by muse, varscan2
- AIDA | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV60663816; called by muse, mutect2
- AK7 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50871355; called by muse, mutect2
- AK9 | c.3225G>C p.Q1075H | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58142010; called by muse, mutect2, varscan2
- AKAP11 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV50296841; called by muse, mutect2, varscan2
- AKAP8 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs571638097, COSV54100847, COSV99511856; called by muse, mutect2, varscan2
- AKIP1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as COSV55148903; called by muse, mutect2, varscan2
- AKNAD1 | c.1114C>G p.Q372E | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV62198217; called by muse, mutect2
- AKR1C2 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 55/174 reads (32%) | catalogued as COSV66333092; called by muse, mutect2, varscan2
- ALPK2 | c.2075C>G p.S692* | Nonsense Mutation (SNP) | VAF 33/142 reads (23%) | catalogued as COSV64492891; called by muse, mutect2, varscan2
- AMIGO1 | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV63990378; called by muse, mutect2, varscan2
- ANK1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV55874984, COSV55880954; called by muse, mutect2
- ANKDD1A | c.1039G>T p.G347W | Missense Mutation (SNP) | VAF 78/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63087604; called by muse, mutect2, varscan2
- ANKFY1 | c.2053G>C p.D685H (on ENST00000341657 / NM_001330063.2; = p.D686H on NM_016376.5) | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58917397; called by muse, mutect2, varscan2
- ANKRD26 | c.4273A>T p.T1425S | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV65775370; called by muse, mutect2, varscan2
- ANKRD7 | c.34A>T p.N12Y | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV54554696; called by muse, mutect2
- ANO6 | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV57660716; called by muse, mutect2, varscan2
- ANXA13 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51623160; called by muse, mutect2, varscan2
- APOBEC1 | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV57548869, COSV57550365; called by muse, mutect2
- APOC2 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52990280; called by muse, mutect2, varscan2
- APPL2 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV51590183; called by muse, mutect2, varscan2
- AQP6 | c.848G>C p.*283Sext*35 | Nonstop Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100210277, COSV59646279; called by muse, mutect2
- AREL1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.621); catalogued as COSV62666376; called by muse, mutect2, varscan2
- ARFGAP2 | c.1286A>G p.K429R | Missense Mutation (SNP) | VAF 70/473 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53565585; called by muse, mutect2, varscan2
- ARFGEF1 | c.3060G>C p.Q1020H | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as COSV51608033; called by muse, mutect2, varscan2
- ARHGAP31 | c.3349G>T p.D1117Y | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51792662; called by muse, mutect2, varscan2
- ARHGEF12 | c.3211G>C p.D1071H | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63104498; called by muse, mutect2, varscan2
- ARID2 | c.1119A>C p.R373S | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV57603158; called by muse, mutect2, varscan2
- ARL4A | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 58/219 reads (26%) | catalogued as COSV63319275; called by muse, mutect2, varscan2
- ARSF | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100839634, COSV63839548; called by muse, mutect2, varscan2
- ARSK | c.297G>C p.W99C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66169635; called by muse, varscan2
- ASCC3 | c.3381G>C p.L1127F | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs772912182, COSV61228258; called by muse, mutect2, varscan2
- ASNSD1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 25/480 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53623690; called by muse, mutect2
- ASTE1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV53908600; called by muse, mutect2, varscan2
- ATAD2 | c.3007G>C p.D1003H | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54880610; called by muse, mutect2
- ATG13 | c.1195C>T p.P399S (on ENST00000359513 / NM_001346321.1; = p.P362S on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV56319003, COSV56319837; called by muse, mutect2, varscan2
- ATG7 | c.1299C>G p.F433L | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.048); catalogued as COSV61612340; called by muse, mutect2, varscan2
- ATP1A2 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV63403660; called by muse, mutect2
- ATP6V0E2 | c.150C>G p.L50= (on ENST00000425642; = p.L99= on NM_145230.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/284 reads (4%) | catalogued as COSV70416512; called by muse, mutect2
- ATP7A | c.4287G>C p.K1429N | Missense Mutation (SNP) | VAF 169/327 reads (52%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.862); catalogued as COSV58445976; called by muse, mutect2, varscan2
- ATPSCKMT | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.158); catalogued as rs533296845, COSV54726773; called by muse, mutect2
- ATR | c.5778G>C p.Q1926H | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63386318; called by muse, mutect2, varscan2
- ATR | c.5059G>C p.D1687H | Missense Mutation (SNP) | VAF 166/599 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63386321; called by muse, mutect2, varscan2
- ATRX | c.4716G>A p.W1572* | Nonsense Mutation (SNP) | VAF 49/213 reads (23%) | catalogued as COSV64876236; called by muse, mutect2, varscan2
- AXDND1 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV62642385; called by muse, mutect2
- BAIAP2 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.366); catalogued as COSV58335207; called by muse, mutect2, varscan2
- BAZ1A | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62410135; called by muse, mutect2
- BAZ1A | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV62410141; called by muse, mutect2, varscan2
- BAZ2B | c.5157G>A p.W1719* | Nonsense Mutation (SNP) | VAF 10/189 reads (5%) | catalogued as COSV58600324; called by muse, mutect2
- BBOF1 | c.1119G>C p.Q373H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV67454943, COSV67454950; called by muse, mutect2, varscan2
- BMT2 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV51774754, COSV51776523; called by muse, mutect2, varscan2
- BOLL | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777269851, COSV56574290, COSV56575790; called by muse, mutect2, varscan2
- BPIFB4 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs747637208, COSV64951156; called by muse, mutect2, varscan2
- BPIFC | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT tolerated (0.72); PolyPhen benign (0.066); catalogued as COSV53278647; called by muse, mutect2
- BRD3 | c.277A>T p.N93Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV57703565; called by muse, mutect2, varscan2
- BRICD5 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV57028022; called by muse, mutect2, varscan2
- BSX | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1477179313, COSV58005541; called by muse, mutect2, varscan2
- BTAF1 | c.1773G>C p.L591F | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56433711; called by muse, mutect2, varscan2
- BTAF1 | c.2695C>T p.Q899* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV56433725; called by muse, mutect2, varscan2
- BTN2A1 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV57003306, COSV57005019; called by muse, mutect2
- C12orf66 | c.991C>G p.H331D | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV61323140; called by muse, mutect2, varscan2
- C1QTNF5 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100264920; called by muse, mutect2, varscan2
- C1RL | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV56924920; called by muse, mutect2
- C2CD2L | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs1345476891, COSV100371153, COSV60884010; called by muse, mutect2, varscan2
- C2orf16 | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68646010; called by muse, mutect2, varscan2
- C2orf16 | c.2597C>G p.S866C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV62675410; called by muse, mutect2, varscan2
- C4B | c.3518C>G p.S1173* | Nonsense Mutation (SNP) | VAF 39/341 reads (11%) | catalogued as COSV70313405; called by muse, mutect2, varscan2
- C4orf45 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV71701047; called by muse, mutect2, varscan2
- C5orf49 | c.251A>G p.H84R | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV67708420; called by muse, mutect2, varscan2
- C8orf37 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV54412464; called by muse, mutect2, varscan2
- CA11 | c.450C>G p.N150K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV50033017; called by muse, mutect2
- CA14 | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 117/887 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV52528964; called by muse, mutect2, varscan2
- CABIN1 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 142/592 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54081496; called by muse, mutect2, varscan2
- CACHD1 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV51552847; called by muse, mutect2, varscan2
- CACNA1D | c.2428G>C p.E810Q (on ENST00000350061 / NM_001128840.3; = p.E830Q on NM_000720.4) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV55446265; called by muse, mutect2, varscan2
- CACNA1H | c.3032T>C p.V1011A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61989737; called by muse, mutect2
- CALD1 | c.2029A>C p.S677R (on ENST00000361675 / NM_033138.4; = p.S422R on NM_004342.7) | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62647731; called by muse, mutect2, varscan2
- CAMLG | c.700A>T p.S234C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs753199494, COSV51804671; called by muse, mutect2, varscan2
- CAMSAP2 | c.754G>C p.G252R (on ENST00000236925 / NM_001297707.2; = p.G241R on NM_203459.3) | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV52670105, COSV99373350; called by muse, mutect2
- CAMSAP2 | c.755G>T p.G252V (on ENST00000236925 / NM_001297707.2; = p.G241V on NM_203459.3) | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.337); catalogued as COSV52670111; called by muse, mutect2
- CAMSAP2 | c.3934G>C p.E1312Q (on ENST00000236925 / NM_001297707.2; = p.E1301Q on NM_203459.3) | Missense Mutation (SNP) | VAF 55/491 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV52670120; called by muse, mutect2, varscan2
- CAMTA1 | c.4909G>C p.D1637H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV57899219; called by muse, mutect2, varscan2
- CASKIN2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs776829959, COSV58595407; called by muse, mutect2, varscan2
- CASP8AP2 | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52746823; called by muse, mutect2
- CASP8AP2 | c.3197A>G p.H1066R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV52746833; called by muse, mutect2, varscan2
- CASP8AP2 | c.5404C>A p.P1802T | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as COSV52746839; called by muse, mutect2, varscan2
- CATSPERG | c.2337C>G p.F779L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV53048558; called by muse, mutect2, varscan2
- CAVIN2 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV58424103, COSV58424299; called by muse, mutect2, varscan2
- CBFA2T3 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51926504, COSV51926740; called by muse, mutect2, varscan2
- CBLN1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV99535799; called by mutect2, varscan2
- CCAR1 | c.2284G>C p.E762Q | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56269659; called by muse, mutect2, varscan2
- CCDC170 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV53340652; called by muse, mutect2, varscan2
- CCDC33 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs766179368, COSV58351549; called by muse, mutect2, varscan2
- CCDC40 | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV53899367; called by muse, mutect2, varscan2
- CCDC85A | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.533); catalogued as rs370940744, COSV68150643; called by muse, mutect2, varscan2
- CCDC88A | c.3054G>C p.Q1018H | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV55061335; called by muse, varscan2
- CCDC88C | c.2211G>T p.K737N | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV66237769; called by muse, mutect2, varscan2
- CCNB3 | c.3147G>C p.L1049F | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV52069592, COSV52073149; called by muse, mutect2, varscan2
- CD109 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV54647934, COSV54655580; called by muse, mutect2, varscan2
- CD163 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 48/826 reads (6%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.685); catalogued as COSV63131450, COSV63132028; called by muse, mutect2
- CDC16 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV52959474; called by muse, mutect2, varscan2
- CDC42 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV59662030; called by muse, mutect2, varscan2
- CDH12 | c.1514A>T p.Q505L | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66403561; called by muse, mutect2, varscan2
- CDH12 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779829463, COSV66403568; called by muse, varscan2
- CDH12 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV66403573; called by muse, varscan2
- CDH4 | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as rs772656062, COSV64653767; called by muse, mutect2, varscan2
- CDHR2 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV56138488; called by muse, mutect2, varscan2
- CDRT1 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99887861; called by muse, mutect2, varscan2
- CEACAM5 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55752138; called by muse, mutect2, varscan2
- CEP112 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.224); catalogued as COSV67139139; called by muse, mutect2, varscan2
- CEP68 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV53124818; called by muse, mutect2, varscan2
- CERKL | c.1486A>G p.K496E (on ENST00000339098 / NM_001030311.2; = p.K470E on NM_201548.5) | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV59207286; called by muse, mutect2, varscan2
- CFAP43 | c.3612G>C p.L1204F | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63853040, COSV63853788; called by muse, mutect2, varscan2
- CHD1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV52339987; called by muse, mutect2, varscan2
- CHERP | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52224284; called by muse, mutect2, varscan2
- CHL1 | c.1597G>C p.E533Q (on ENST00000397491 / NM_001253387.1; = p.E549Q on NM_006614.4) | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV56592860; called by muse, mutect2, varscan2
- CHRNB4 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55715979, COSV55718601; called by muse, mutect2, varscan2
- CHST6 | c.1103G>C p.R368P | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV59999424, COSV60000035; called by muse, mutect2, varscan2
- CHTOP | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV64154946, COSV64155070; called by muse, mutect2
- CILK1 | c.1541C>T p.S514L (on ENST00000350082 / NM_001375397.1; = p.S507L on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as rs535382697, COSV63154133; called by muse, mutect2, varscan2
- CILP2 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV52274801, COSV52281504; called by muse, mutect2, varscan2
- CILP2 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs147931006, COSV52274817; called by muse, mutect2, varscan2
- CLIP1 | c.3328G>T p.E1110* (on ENST00000620786 / NM_001247997.1; = p.E1099* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 50/166 reads (30%) | catalogued as COSV56801483; called by muse, mutect2, varscan2
- CLMN | c.2181C>G p.F727L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV54181920; called by muse, mutect2, varscan2
- CLMN | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54181929; called by muse, mutect2, varscan2
- CLUH | c.733G>A p.E245K (on ENST00000435359; = p.E283K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889303135, COSV70928631; called by muse, mutect2, varscan2
- CNGA1 | c.1714C>T p.L572F | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62054231; called by mutect2, varscan2
- CNGA1 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs1259872554, COSV62054238; called by muse, mutect2, varscan2
- CNGA3 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs779119081, COSV55624193; called by muse, mutect2, varscan2
- CNGB3 | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV60689361; called by muse, mutect2, varscan2
- CNGB3 | c.997T>A p.S333T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.206); catalogued as COSV60689368; called by muse, mutect2, varscan2
- CNNM3 | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.395); catalogued as COSV59709160; called by muse, varscan2
- CNTN4 | c.2620C>T p.H874Y | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61872581; called by muse, mutect2, varscan2
- CNTNAP5 | c.425A>C p.K142T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV70484956; called by muse, mutect2, varscan2
- COA4 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60155471; called by muse, mutect2, varscan2
- COL19A1 | c.1898C>G p.A633G | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV59572169; called by muse, mutect2, varscan2
- COL1A1 | c.4244G>T p.C1415F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56804738; called by muse, varscan2
- COL22A1 | c.4703G>T p.G1568V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57335834; called by muse, mutect2, varscan2
- COL24A1 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65305852; called by muse, mutect2
- COL28A1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68081905; called by muse, mutect2, varscan2
- COL5A2 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as COSV66408231, COSV66409549; called by muse, mutect2
- COL8A1 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53734121; called by muse, mutect2, varscan2
- COL9A2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV65607494; called by muse, mutect2
- COPS4 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.15); catalogued as COSV52314856; called by muse, mutect2, varscan2
- CPN1 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV64942243; called by muse, mutect2, varscan2
- CPO | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV55939745; called by muse, mutect2, varscan2
- CPS1 | c.2693C>G p.S898C | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV51809374; called by muse, mutect2, varscan2
- CREB3L4 | c.590T>A p.L197Q | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55132064; called by muse, mutect2, varscan2
- CROCC | c.3102G>C p.E1034D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV65011927; called by muse, mutect2
- CRYZ | c.267A>T p.K89N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.671); catalogued as COSV61717714; called by muse, mutect2, varscan2
- CSF3R | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV58966608; called by muse, mutect2, varscan2
- CSMD3 | c.8324C>G p.T2775S (on ENST00000297405 / NM_001363185.1; = p.T2606S on NM_052900.3) | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as COSV52173670; called by muse, mutect2, varscan2
- CSMD3 | c.3001G>A p.E1001K (on ENST00000297405 / NM_001363185.1; = p.E897K on NM_052900.3) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52173695; called by muse, mutect2, varscan2
- CSTF2T | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV58656069, COSV58656419; called by muse, mutect2, varscan2
- CUL3 | c.2252G>C p.R751T | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52364584; called by muse, mutect2
- CUL9 | c.607C>G p.H203D | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV52728299; called by muse, mutect2, varscan2
- CUL9 | c.871A>G p.R291G | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV52728306; called by muse, mutect2, varscan2
- CWF19L2 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV56512166; called by muse, mutect2, varscan2
- CYLD | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61094566; called by muse, mutect2, varscan2
- CYP11B1 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as CM100847, COSV52826929; called by muse, mutect2, varscan2
- CYP24A1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs758415328, COSV53774028, COSV53775862; called by muse, mutect2
- CYP2S1 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59506033; called by muse, mutect2, varscan2
- CYP3A43 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV55936030; called by muse, mutect2
- CYP3A7 | c.1189C>G p.P397A | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60481462; called by muse, mutect2, varscan2
- DAB1 | c.1314G>C p.K438N (on ENST00000371231; = p.K405N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs568914253, COSV64692856; called by muse, mutect2, varscan2
- DBT | c.1214G>C p.G405A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64495429; called by muse, mutect2, varscan2
- DCAF6 | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV56578432; called by muse, mutect2, varscan2
- DDHD1 | c.1759G>C p.E587Q (on ENST00000323669; = p.E784Q on NM_030637.3) | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as COSV60359094; called by muse, mutect2, varscan2
- DDIAS | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV100231048, COSV61271407, COSV61272041; called by muse, mutect2, varscan2
- DDIAS | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV61272049; called by muse, mutect2, varscan2
- DEPDC5 | c.3853G>C p.E1285Q (on ENST00000400246; = p.E1354Q on NM_014662.5) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56697045; called by muse, mutect2
- DHTKD1 | c.2152C>G p.Q718E | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV53803184, COSV53803416; called by muse, mutect2, varscan2
- DIDO1 | c.4552G>A p.D1518N | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV56621708; called by muse, mutect2, varscan2
- DIP2C | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 23/145 reads (16%) | catalogued as COSV55157213, COSV55166969; called by muse, mutect2, varscan2
- DLEC1 | c.4372G>C p.D1458H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV57299371; called by muse, mutect2
- DLG2 | c.2589G>T p.W863C | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54642351, COSV99712529; called by muse, mutect2, varscan2
- DMD | c.8833G>A p.E2945K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV58909168; called by muse, mutect2, varscan2
- DMD | c.6288A>G p.Q2096= | Splice Region (SNP) | VAF 51/115 reads (44%) | catalogued as COSV63753364; called by muse, mutect2, varscan2
- DMXL2 | c.1998G>C p.L666F | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51846000; called by muse, mutect2, varscan2
- DNAAF3 | c.1072A>G p.T358A (on ENST00000524407 / NM_001256715.2; = p.T405A on NM_178837.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61276874; called by muse, mutect2
- DNAAF6 | c.418A>G p.S140G | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV60495777; called by muse, mutect2, varscan2
- DNAH10 | c.3019C>T p.Q1007* (on ENST00000409039; = p.Q946* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV68993338; called by muse, mutect2, varscan2
- DNAH17 | c.11977G>C p.E3993Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67753952, COSV67754757; called by muse, mutect2, varscan2
- DNAH8 | c.7336G>T p.A2446S | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.646); catalogued as rs1272485320, COSV59443752; called by muse, mutect2, varscan2
- DNAH8 | c.8347G>C p.E2783Q | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59443758; called by muse, mutect2, varscan2
- DNAH8 | c.9383A>T p.D3128V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59443767; called by muse, mutect2, varscan2
- DNAI2 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56758588; called by muse, mutect2, varscan2
- DNAJC14 | c.233del p.P78Qfs*178 | Frame Shift Del (DEL) | VAF 49/460 reads (11%) | catalogued as rs760590976; called by mutect2, pindel, varscan2
- DNAJC30 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs781836501, COSV56094929; called by muse, mutect2, varscan2
- DNM1 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.981); catalogued as COSV57851054, COSV57851420, COSV57852347; called by muse, mutect2, varscan2
- DPF3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1313292844, COSV63498471; called by muse, mutect2, varscan2
- DPH7 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53022158; called by muse, mutect2, varscan2
- DPP10 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.232); catalogued as rs962555498, COSV59684641; called by muse, mutect2
- DPP8 | c.535C>G p.L179V (on ENST00000341861 / NM_001320875.2; = p.L163V on NM_017743.6) | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.456); catalogued as COSV100202163, COSV55678448; called by muse, mutect2, varscan2
- DRG1 | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58918668; called by muse, mutect2, varscan2
- DROSHA | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV60775710; called by muse, mutect2, varscan2
- DSCAML1 | c.2742C>G p.L914= (on ENST00000321322; = p.L854= on NM_020693.4) | Splice Region (SNP) | VAF 10/104 reads (10%) | catalogued as rs913661364, COSV58390046; called by muse, mutect2
- DSE | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV59063779; called by muse, mutect2, varscan2
- DSP | c.6639C>G p.I2213M | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV101131150, COSV65791675; called by muse, mutect2
- DST | c.8770G>C p.E2924Q | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99749655; called by muse, mutect2, varscan2
- DST | c.2189G>C p.R730T (on ENST00000361203 / NM_001374722.1; = p.R404T on NM_001723.6) | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV55013187, COSV55026350; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1294A>T p.R432W | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV50051513; called by muse, mutect2, varscan2
- DUSP7 | c.636C>G p.I212M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56589027; called by muse, mutect2, varscan2
- DZIP1 | c.2492del p.G831Afs*21 (on ENST00000347108; = p.G812Afs*21 on NM_014934.5) | Frame Shift Del (DEL) | VAF 86/246 reads (35%) | catalogued as COSV100714232; called by mutect2, pindel, varscan2
- E2F1 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55775991; called by muse, mutect2, varscan2
- EBF1 | c.806C>G p.P269R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565887, COSV100566474, COSV58177454; called by muse, mutect2, varscan2
- EDNRA | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 72/330 reads (22%) | catalogued as COSV60097411; called by muse, mutect2, varscan2
- EGR2 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV54346874; called by muse, mutect2, varscan2
- EHBP1 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV50419828; called by muse, mutect2, varscan2
- EHD4 | c.1510T>G p.F504V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55004654; called by muse, mutect2, varscan2
- ELANE | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV55048020; called by muse, mutect2, varscan2
- ELL2 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV52982372; called by muse, varscan2
- ENPP2 | c.1567C>G p.P523A (on ENST00000075322 / NM_001040092.3; = p.P575A on NM_006209.5) | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV50014427; called by muse, mutect2, varscan2
- EPHA7 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV65180016, COSV65182300; called by muse, mutect2
- EPN3 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs764261827, COSV52139775; called by muse, mutect2, varscan2
- EPS15 | c.2594G>A p.R865K | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.07); catalogued as COSV65542125; called by muse, mutect2, varscan2
- ERAS | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1557033060, COSV54432729; called by muse, mutect2, varscan2
- ERBB4 | c.1390A>G p.S464G | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.164); catalogued as COSV53530113; called by muse, mutect2, varscan2
- ERICH3 | c.4543C>A p.Q1515K | Missense Mutation (SNP) | VAF 367/682 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV58606096; called by muse, mutect2, varscan2
- ERICH3 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.655); catalogued as COSV100445363, COSV58606106; called by muse, mutect2, varscan2
- ESYT3 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV67440837; called by muse, mutect2, varscan2
- ETV6 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67149770, COSV67152978; called by muse, mutect2
- EVPL | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV56910702; called by muse, mutect2
- EXPH5 | c.3088C>T p.L1030F | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as rs772142292, COSV56202072, COSV56209380; called by muse, mutect2
- F8 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV64273221; called by muse, mutect2, varscan2
- FAM107A | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV62980625; called by muse, mutect2, varscan2
- FAM120B | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53003622; called by muse, mutect2
- FAM13A | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV52002112; called by muse, mutect2, varscan2
- FAM169A | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1561317470, COSV65846475; called by muse, mutect2, varscan2
- FAM171B | c.2120C>G p.S707C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59003272; called by muse, mutect2, varscan2
- FAM20B | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs371494390; called by muse, mutect2, varscan2
- FAM47C | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs782267927, COSV63724853, COSV63726402; called by muse, mutect2, varscan2
- FANK1 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64158260; called by muse, mutect2, varscan2
- FARS2 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as COSV51164425; called by muse, mutect2, varscan2
- FAT4 | c.3941C>G p.S1314C | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV67886071; called by muse, mutect2, varscan2
- FBN2 | c.3724G>C p.D1242H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52511365, COSV99327338; called by muse, mutect2, varscan2
- FCAR | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV62029575; called by muse, mutect2, varscan2
- FCGBP | c.11701C>G p.Q3901E | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs551816320; called by muse, mutect2
- FCGR3A | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); catalogued as rs1432441073, COSV63459545; called by muse, mutect2
- FCRL5 | c.1214G>C p.R405T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV100709120, COSV62514276; called by muse, mutect2, varscan2
- FGB | c.1022T>C p.L341S | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57418227; called by muse, mutect2, varscan2
- FGFR4 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766706277, COSV52801567, COSV52803164; called by muse, mutect2, varscan2
- FHOD1 | c.3162G>C p.K1054N | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV50760641; called by muse, mutect2, varscan2
- FKBP9 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV54230659, COSV54234345; called by muse, mutect2, varscan2
- FLG | c.10108G>C p.E3370Q | Missense Mutation (SNP) | VAF 93/979 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV64241565; called by muse, mutect2, varscan2
- FLT1 | c.1869C>G p.I623M | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV56727227; called by muse, mutect2, varscan2
- FN1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.3); catalogued as COSV60552298; called by muse, mutect2, varscan2
- FNBP4 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.302); catalogued as rs748703382, COSV55448415; called by muse, mutect2, varscan2
- FNDC1 | c.4782C>G p.I1594M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV51937261; called by muse, mutect2, varscan2
- FREM2 | c.7243G>C p.D2415H | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs563216892, COSV54832421, COSV54837001; called by muse, mutect2, varscan2
- FRMD8 | c.483C>G p.Y161* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV58212492; called by muse, mutect2
- FSCB | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.276); catalogued as COSV61217900; called by muse, mutect2, varscan2
- FSHB | c.202A>T p.T68S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV54221744; called by muse, mutect2
- FSIP2 | c.17876A>G p.Q5959R | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100556248; called by muse, mutect2, varscan2
- FTH1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 55/626 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV56445206; called by muse, mutect2
- FUT10 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV59451288; called by muse, mutect2, varscan2
- GALNT5 | c.2465G>A p.C822Y | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754488770, COSV52037685; called by muse, mutect2
- GATA6 | c.1787G>C p.*596Sext*55 | Nonstop Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52525497; called by muse, mutect2, varscan2
- GBP4 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV63252904, COSV63254217; called by muse, mutect2, varscan2
- GBX1 | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 109/804 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV52547493; called by muse, mutect2, varscan2
- GCC1 | c.1553A>T p.E518V | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58462491; called by muse, mutect2, varscan2
- GCK | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs763870160, COSV60786081; called by muse, mutect2
- GCM2 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65275541; called by muse, mutect2
- GDNF | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV58478288, COSV58479394; called by muse, mutect2, varscan2
- GGTLC1 | c.532-2A>T p.X178_splice | Splice Site (SNP) | VAF 21/154 reads (14%) | catalogued as COSV99046247, COSV99600911; called by muse, mutect2, varscan2
- GHITM | c.389A>T p.Y130F | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV64538481; called by muse, mutect2, varscan2
- GINM1 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as COSV66389788; called by muse, mutect2
- GLI1 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 52/416 reads (13%) | catalogued as COSV57361621; called by muse, mutect2, varscan2
- GLYATL1 | c.186+1G>A p.X62_splice (on ENST00000317391 / NM_001354699.1; = p.X93_splice on NM_080661.4) | Splice Site (SNP) | VAF 23/96 reads (24%) | catalogued as COSV55608739; called by muse, mutect2
- GNL1 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.063); catalogued as COSV64835201; called by muse, mutect2, varscan2
- GNS | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 76/573 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV50694630; called by muse, mutect2, varscan2
- GOLGA3 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 28/166 reads (17%) | catalogued as COSV52630775; called by muse, mutect2
- GOLGB1 | c.3097G>C p.E1033Q | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.447); catalogued as COSV100511595, COSV61465606; called by muse, mutect2
- GPAA1 | c.374C>G p.S125W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV60155679; called by muse, mutect2, varscan2
- GPATCH8 | c.195G>A p.G65= | Splice Region (SNP) | VAF 54/132 reads (41%) | catalogued as rs752210516, COSV59194788; called by muse, mutect2, varscan2
- GPM6A | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54541548; called by muse, mutect2, varscan2
- GPR12 | c.161C>G p.S54W | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67344320; called by muse, mutect2, varscan2
- GRIN2B | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV74205829; called by muse, mutect2, varscan2
- GRM3 | c.134T>A p.F45Y | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64471379; called by muse, mutect2, varscan2
- GRM8 | c.1788del p.I596Mfs*6 | Frame Shift Del (DEL) | VAF 27/110 reads (25%) | catalogued as COSV100286782; called by mutect2, pindel, varscan2
- GRM8 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58824093; called by muse, varscan2
- GSTM4 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 150/957 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV58694563; called by muse, mutect2, varscan2
- GTF2I | c.2635A>G p.K879E (on ENST00000573035 / NM_032999.4; = p.K838E on NM_001518.5) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100259890; called by muse, mutect2, varscan2
- GUCA1C | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV51719495; called by muse, mutect2, varscan2
- H2AW | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV64209724; called by muse, mutect2, varscan2
- H3C4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV61911648, COSV61911890; called by muse, mutect2, varscan2
- H3C4 | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV61911892, COSV61912145; called by muse, mutect2, varscan2
- HAO1 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1398514741, COSV66491931; called by muse, mutect2, varscan2
- HDAC4 | c.2837A>G p.Y946C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61864908; called by muse, mutect2, varscan2
- HEATR5B | c.2581C>G p.L861V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV51852447; called by muse, mutect2, varscan2
- HENMT1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.198); catalogued as rs370205325; called by muse, mutect2, varscan2
- HERC6 | c.2186C>G p.T729S | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV52029815; called by muse, varscan2
- HHAT | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV54798404, COSV54804822; called by muse, mutect2, varscan2
- HLX | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV65044786; called by muse, mutect2
- HNRNPH1 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.722); catalogued as COSV100270939, COSV61484861; called by muse, mutect2, varscan2
- HOXB9 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1291560837, COSV60817068; called by muse, mutect2, varscan2
- HOXC10 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.745); catalogued as rs1245618029, COSV57726211; called by muse, mutect2, varscan2
- HSP90B1 | c.822C>G p.F274L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55355249; called by muse, mutect2, varscan2
- HSPG2 | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV65930309; called by muse, mutect2, varscan2
- HTR1F | c.985T>C p.S329P | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as rs1373982517, COSV60389648; called by muse, mutect2, varscan2
- HTRA2 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 66/454 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51207439; called by muse, mutect2, varscan2
- HUNK | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.195); catalogued as COSV54228088; called by muse, mutect2, varscan2
- HYOU1 | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV68215724; called by muse, mutect2, varscan2
- ICAM1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.196); catalogued as rs143008699, COSV99320913; called by muse, mutect2
- ICAM5 | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55747233; called by muse, mutect2
- IFI27 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV54140771; called by muse, mutect2, varscan2
- IFNAR1 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV54251944; called by muse, mutect2, varscan2
- IFT81 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 47/350 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV54360513; called by muse, mutect2, varscan2
- IMPG2 | c.667-1G>C p.X223_splice | Splice Site (SNP) | VAF 17/102 reads (17%) | catalogued as COSV51977908; called by muse, mutect2
- INPP1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746741158, COSV59415754; called by muse, mutect2, varscan2
- INPPL1 | c.680C>G p.S227* | Nonsense Mutation (SNP) | VAF 33/213 reads (15%) | catalogued as COSV53355380; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 10/234 reads (4%) | catalogued as COSV67332692; called by muse, mutect2
- IQGAP1 | c.1288C>G p.Q430E | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV51585367; called by muse, mutect2
- IQGAP3 | c.3030C>G p.F1010L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100752255, COSV63251289; called by muse, mutect2, varscan2
- IQSEC3 | c.1084G>C p.E362Q (on ENST00000538872 / NM_001170738.2; = p.E59Q on NM_015232.1) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs782138378, COSV58280802, COSV58284590; called by muse, mutect2, varscan2
- ISM2 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV53635009; called by muse, mutect2, varscan2
- ITGA6 | c.2452C>G p.Q818E (on ENST00000442250; = p.Q779E on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51224430; called by muse, mutect2
- ITGAE | c.303C>A p.H101Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.731); catalogued as COSV53993600, COSV53995870; called by muse, mutect2, varscan2
- ITIH1 | c.1919G>C p.R640T | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV56254823; called by muse, mutect2, varscan2
- ITPR1 | c.2740G>A p.E914K (on ENST00000354582; = p.E899K on NM_002222.7) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.358); catalogued as COSV56980610; called by muse, mutect2
- ITPRID2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57471595; called by muse, mutect2, varscan2
- ITPRIP | c.528G>C p.R176S | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53391463; called by muse, mutect2
- IVNS1ABP | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 72/759 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62251003; called by muse, mutect2
- IVNS1ABP | c.893C>G p.S298* | Nonsense Mutation (SNP) | VAF 38/392 reads (10%) | catalogued as COSV62251011; called by muse, mutect2
- JTB | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV55131691; called by muse, mutect2, varscan2
- KANK2 | c.2493C>G p.I831M (on ENST00000586659 / NM_001379562.1; = p.I839M on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as COSV62007834; called by muse, mutect2
- KANK4 | c.1227G>C p.Q409H | Missense Mutation (SNP) | VAF 58/427 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV62986681; called by muse, mutect2, varscan2
- KAT6A | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 20/144 reads (14%) | catalogued as COSV55905851; called by muse, mutect2, varscan2
- KAT6A | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55905861; called by muse, mutect2, varscan2
- KAT6A | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55905871; called by muse, mutect2, varscan2
- KATNAL2 | c.1586C>T p.S529L (on ENST00000356157 / NM_001353899.1; = p.S457L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55298604; called by muse, mutect2, varscan2
- KCNA4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV60252040, COSV60255677; called by muse, mutect2, varscan2
- KCND2 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58579085, COSV58594496; called by muse, mutect2, varscan2
- KCNH8 | c.2237A>T p.K746I | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV60463064; called by muse, mutect2, varscan2
- KCNJ3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54535808; called by muse, mutect2
- KCNJ4 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57857021; called by muse, mutect2
- KCNN2 | c.1475T>A p.M492K (on ENST00000264773; = p.M704K on NM_021614.4) | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV53288146; called by muse, mutect2, varscan2
- KCNQ5 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 144/658 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV59659006; called by muse, mutect2, varscan2
- KCTD8 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV63588858; called by muse, mutect2, varscan2
- KDM6B | c.2194C>G p.L732V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV54681335; called by muse, mutect2, varscan2
- KHDRBS3 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1337762374, COSV63418123; called by muse, mutect2, varscan2
- KIAA0895L | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV51782843; called by muse, mutect2, varscan2
- KIAA0930 | c.485A>T p.N162I (on ENST00000336156 / NM_001009880.2; = p.N167I on NM_015264.2) | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52663186; called by muse, mutect2, varscan2
- KIAA1109 | c.6703G>C p.E2235Q | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV52671922; called by muse, mutect2, varscan2
- KIAA1109 | c.13370G>A p.R4457K | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.814); catalogued as COSV52671934; called by muse, mutect2
- KIDINS220 | c.1462G>C p.G488R | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.654); catalogued as COSV56753265, COSV99876367; called by muse, mutect2
- KIF16B | c.1785-1G>C p.X595_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV61703316, COSV61705826; called by muse, mutect2, varscan2
- KIFAP3 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as rs771901370, COSV63033531; called by muse, mutect2, varscan2
- KIFAP3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63033540; called by muse, mutect2, varscan2
- KLHDC1 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 24/119 reads (20%) | catalogued as COSV63778766; called by muse, mutect2, varscan2
- KLHL20 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52941835; called by muse, mutect2, varscan2
- KLKB1 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52995524; called by muse, mutect2, varscan2
- KLRB1 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV57589702; called by muse, mutect2
- KLRC1 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 53/559 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as rs1037396299, COSV61725186; called by muse, mutect2
- KMT2B | c.7305G>A p.W2435* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV55820525; called by muse, varscan2
- KMT2C | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51436714; called by muse, mutect2, varscan2
- KMT5B | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58565918; called by muse, mutect2
- KMT5B | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58565928; called by muse, mutect2, varscan2
- KNL1 | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV61154542, COSV61160683; called by muse, mutect2, varscan2
- KNL1 | c.601A>C p.T201P (on ENST00000346991 / NM_170589.5; = p.T175P on NM_144508.5) | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV61154556; called by muse, mutect2, varscan2
- KRT77 | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59239659; called by muse, mutect2, varscan2
- KRTAP10-2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV59961315; called by muse, mutect2, varscan2
- LAG3 | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 41/458 reads (9%) | catalogued as COSV52567417; called by muse, mutect2
- LAMA4 | c.4874G>T p.G1625V (on ENST00000230538 / NM_001105206.3; = p.G1618V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57896458; called by muse, mutect2, varscan2
- LGALS12 | c.89C>G p.T30R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV55370202; called by muse, mutect2, varscan2
- LGI3 | c.1288C>G p.R430G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV60443111, COSV60443347; called by muse, mutect2, varscan2
- LHX8 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV53956548; called by muse, mutect2
- LIMCH1 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV58282748; called by muse, mutect2, varscan2
- LMBRD1 | c.1519C>T p.H507Y (on ENST00000649011; = p.H485Y on NM_018368.4) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.69); catalogued as rs762697760, COSV65297127; called by muse, mutect2, varscan2
- LNPK | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV55823644; called by muse, mutect2, varscan2
- LONRF1 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | catalogued as COSV68036768; called by muse, mutect2, varscan2
- LONRF3 | c.1541C>G p.S514* (on ENST00000371628 / NM_001031855.3; = p.S473* on NM_024778.5) | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as COSV59151998; called by muse, mutect2, varscan2
- LPAR4 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV70912566, COSV70913606; called by muse, mutect2, varscan2
- LRP1B | c.12928C>T p.H4310Y | Missense Mutation (SNP) | VAF 212/577 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67216545; called by muse, mutect2, varscan2
- LRP1B | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 52/467 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67210169; called by muse, mutect2, varscan2
- LRP2 | c.4963G>C p.V1655L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.984); catalogued as COSV55552304; called by muse, mutect2, varscan2
- LRPPRC | c.4171G>T p.E1391* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as COSV53238058; called by muse, mutect2, varscan2
- LRRC36 | c.1634C>G p.S545C | Missense Mutation (SNP) | VAF 87/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52079600, COSV52081320; called by muse, mutect2, varscan2
- LRRC4C | c.1253T>G p.V418G | Missense Mutation (SNP) | VAF 54/440 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53424999; called by muse, mutect2, varscan2
- LRRC7 | c.1267T>C p.F423L (on ENST00000651989 / NM_001370785.2; = p.F390L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV50452331; called by muse, mutect2, varscan2
- LRRK2 | c.769A>G p.M257V | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV54152622; called by muse, mutect2, varscan2
- LRRN2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV65783716; called by muse, mutect2, varscan2
- LSM4 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53253617; called by muse, mutect2, varscan2
- LTK | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99541157; called by muse, mutect2, varscan2
- LUM | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57128073, COSV57128196; called by muse, mutect2, varscan2
- LY9 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV54433881; called by muse, mutect2
- LY9 | c.1442G>C p.R481P | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54433898, COSV99627272; called by muse, mutect2, varscan2
- LYST | c.5989G>T p.A1997S | Missense Mutation (SNP) | VAF 68/586 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.058); catalogued as COSV67706184, COSV67706774; called by muse, mutect2, varscan2
- LYST | c.4522G>T p.D1508Y | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV67706780; called by muse, mutect2
- MAB21L3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV65673847; called by muse, mutect2, varscan2
- MACF1 | c.17764G>C p.D5922H (on ENST00000372915; = p.D3967H on NM_012090.5) | Missense Mutation (SNP) | VAF 58/572 reads (10%) | catalogued as COSV57120123; called by muse, mutect2, varscan2
- MAGEC2 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55999189; called by muse, mutect2, varscan2
- MAGEE1 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV63910121; called by muse, mutect2, varscan2
- MAGI2 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 23/270 reads (9%) | catalogued as COSV62656230, COSV99073976; called by muse, mutect2
- MAML1 | c.2643C>G p.F881L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV52985135; called by muse, mutect2, varscan2
- MAN1C1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV56044849; called by muse, mutect2, varscan2
- MAN2C1 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as COSV51228665; called by muse, mutect2, varscan2
- MAP1A | c.7747G>A p.E2583K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1379065570, COSV100288567, COSV55807763; called by muse, mutect2, varscan2
- MAP3K4 | c.868G>C p.A290P | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV62333324; called by muse, mutect2, varscan2
- MAP3K6 | c.3768C>A p.D1256E | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV58871719; called by muse, mutect2, varscan2
- MAPK14 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768171262, COSV57694769; called by muse, mutect2, varscan2
- MARF1 | c.3978G>C p.K1326N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60023193; called by muse, mutect2, varscan2
- MARK4 | c.1894G>C p.E632Q (on ENST00000262891 / NM_001199867.2; = p.L658= on NM_031417.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1360769623, COSV53463720; called by muse, mutect2, varscan2
- MAST2 | c.1687A>T p.I563L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63618031; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MCC | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV56728645; called by muse, mutect2, varscan2
- MCF2L | c.1510G>C p.E504Q (on ENST00000375608; = p.E472Q on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV65050500; called by muse, mutect2, varscan2
- MCF2L2 | c.2500G>T p.D834Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61053158, COSV61053742; called by muse, mutect2
- MCPH1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs752969100, COSV60913248; called by muse, mutect2, varscan2
- MDN1 | c.5053G>C p.E1685Q | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV65521267; called by muse, mutect2, varscan2
- MEAK7 | c.1094A>G p.H365R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59144091; called by muse, mutect2, varscan2
- MEFV | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as COSV54821587; called by muse, mutect2
- MET | c.2092A>T p.T698S | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV59260942; called by muse, mutect2, varscan2
- METTL7A | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1332876486, COSV100153691, COSV59840714; called by muse, mutect2, varscan2
- MIA2 | c.1787-2A>T p.X596_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV54483307; called by muse, mutect2, varscan2
- MLST8 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1206083673, COSV57028006; called by muse, mutect2, varscan2
- MMP24 | c.399G>C p.W133C | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55769961; called by muse, mutect2, varscan2
- MMP9 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs527613229, COSV63434057; called by muse, mutect2
- MON2 | c.2014-1G>T p.X672_splice | Splice Site (SNP) | VAF 48/183 reads (26%) | catalogued as COSV54806896; called by muse, mutect2, varscan2
- MORC1 | c.1032-1G>A p.X344_splice | Splice Site (SNP) | VAF 46/147 reads (31%) | catalogued as COSV51719506; called by muse, mutect2, varscan2
- MORC4 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55241926; called by muse, mutect2, varscan2
- MROH2B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.187); catalogued as COSV68183769; called by muse, mutect2
- MRPL42 | c.48G>C p.L16F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV62355988; called by muse, mutect2, varscan2
- MSLN | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.919); catalogued as COSV53501928; called by muse, mutect2, varscan2
- MTARC2 | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV63764926, COSV63765556; called by muse, mutect2
- MTHFD2 | c.833G>C p.R278T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1200345323, COSV51201370; called by muse, mutect2, varscan2
- MTMR3 | c.2957C>G p.S986* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV60304156; called by muse, mutect2, varscan2
- MTRR | c.2163G>C p.Q721H (on ENST00000264668; = p.Q694H on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52943654; called by muse, mutect2, varscan2
- MTUS2 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV70916709; called by muse, mutect2, varscan2
- MUC16 | c.33416C>G p.S11139* | Nonsense Mutation (SNP) | VAF 16/276 reads (6%) | catalogued as COSV67461322, COSV67464063; called by muse, mutect2
- MUC16 | c.32809C>G p.L10937V | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.11); catalogued as rs746420551, COSV67461182, COSV67484595; called by muse, mutect2
- MUC16 | c.22720G>T p.V7574F | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV67464070; called by muse, mutect2
- MUC16 | c.15373G>C p.E5125Q | Missense Mutation (SNP) | VAF 42/533 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.139); catalogued as COSV67453122, COSV67464076; called by muse, mutect2
- MUC16 | c.6436C>G p.L2146V | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV101199598, COSV67464082, COSV67478986; called by muse, mutect2, varscan2
- MUC16 | c.4499C>G p.S1500* | Nonsense Mutation (SNP) | VAF 132/993 reads (13%) | catalogued as COSV67454497, COSV67464087; called by muse, varscan2
- MUC16 | c.4397C>G p.T1466R | Missense Mutation (SNP) | VAF 76/533 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1441563208, COSV67464092; called by muse, varscan2
- MUC16 | c.3911C>T p.S1304L | Missense Mutation (SNP) | VAF 52/436 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV67452375; called by muse, varscan2
- MUC16 | c.3734C>G p.S1245* | Nonsense Mutation (SNP) | VAF 253/1884 reads (13%) | catalogued as COSV67464105, COSV67470453; called by muse, varscan2
- MUC16 | c.2792C>G p.S931* | Nonsense Mutation (SNP) | VAF 50/303 reads (17%) | catalogued as COSV67462986, COSV67464110, COSV67500250; called by muse, mutect2, varscan2
- MUC16 | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV67464127; called by muse, mutect2
- MUC16 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 17/371 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV67464132; called by muse, mutect2
- MUC17 | c.9655G>A p.E3219K | Missense Mutation (SNP) | VAF 74/607 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV60287856; called by muse, mutect2, varscan2
- MYC | c.916C>G p.Q306E (on ENST00000377970; = p.Q321E on NM_002467.6) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52372547; called by muse, mutect2, varscan2
- MYCBP2 | c.8002G>C p.D2668H (on ENST00000357337; = p.D2706H on NM_015057.5) | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62018132; called by muse, mutect2
- MYH1 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV56848026; called by muse, mutect2, varscan2
- MYH13 | c.2499G>C p.W833C | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52828007; called by muse, mutect2, varscan2
- MYO3B | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 70/450 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs761565297, COSV58702561; called by muse, varscan2
- MYOCD | c.2745C>G p.F915L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100589988, COSV58503227; called by muse, mutect2, varscan2
- MYPN | c.2265G>C p.Q755H | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62733679; called by muse, mutect2, varscan2
- MYPN | c.3574G>C p.E1192Q | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62733686; called by muse, mutect2, varscan2
- NAALAD2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV58960841; called by muse, mutect2
- NADK | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58272099; called by muse, mutect2, varscan2
- NADSYN1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs540999843, COSV59812094; called by muse, mutect2, varscan2
- NAMPT | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55995037; called by muse, mutect2, varscan2
- NASP | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV63113004; called by muse, mutect2
- NAV3 | c.6944G>T p.R2315L (on ENST00000397909 / NM_001024383.2; = p.R2293L on NM_014903.6) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57078453, COSV57096626; called by muse, mutect2, varscan2
- NBEA | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59782025; called by muse, mutect2, varscan2
- NCAPD3 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73198652; called by muse, mutect2, varscan2
- NCDN | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57845534; called by muse, mutect2, varscan2
- NCL | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 28/301 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV59545785; called by muse, mutect2
- NCOA6 | c.954G>C p.W318C | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62863400; called by muse, mutect2, varscan2
- NCOA7 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV57655154; called by muse, mutect2
- NDN | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59359644; called by muse, mutect2, varscan2
- NDN | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59359651; called by muse, mutect2, varscan2
- NEB | c.8588G>C p.S2863T | Missense Mutation (SNP) | VAF 81/563 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.647); catalogued as COSV51369603; called by muse, mutect2, varscan2
- NEK9 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as COSV53130929, COSV53131117; called by muse, mutect2, varscan2
- NEU1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751607058, COSV57667124; called by muse, mutect2
- NEURL2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | catalogued as rs1283461918, COSV51942056; called by muse, mutect2
- NFATC2 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs779382116, COSV65352933; called by muse, mutect2, varscan2
- NGB | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV53611366; called by muse, mutect2, varscan2
- NIN | c.3663A>T p.K1221N | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs1316649238, COSV55389484; called by muse, mutect2, varscan2
- NIPBL | c.6590G>T p.G2197V | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56950488; called by muse, mutect2, varscan2
- NKD1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as rs199950234, COSV51691088; called by muse, mutect2, varscan2
- NLRC4 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV61592567; called by muse, mutect2, varscan2
- NLRP11 | c.1679_1680insCA p.I561Rfs*19 | Frame Shift Ins (INS) | VAF 33/203 reads (16%) | catalogued as COSV100789801; called by mutect2, pindel, varscan2
- NMBR | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV57800889, COSV57801137; called by muse, mutect2, varscan2
- NOX4 | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.268); catalogued as COSV54452697; called by muse, mutect2, varscan2
- NOX4 | c.698G>C p.S233T | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV54452709; called by muse, mutect2, varscan2
- NPAS1 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53409246; called by muse, mutect2, varscan2
- NPY4R | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs782024830, COSV65398029; called by muse, mutect2
- NRBP1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as COSV51994109; called by muse, mutect2, varscan2
- NRCAM | c.964G>A p.E322K (on ENST00000379028 / NM_001371124.1; = p.E316K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61036285; called by muse, mutect2
- NSD3 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.068); catalogued as COSV57618573; called by muse, mutect2
- NT5C1B | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV58395797; called by muse, mutect2
- NUP205 | c.2983C>G p.L995V | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV53656415; called by muse, mutect2, varscan2
- NUP205 | c.4232-2A>C p.X1411_splice | Splice Site (SNP) | VAF 112/828 reads (14%) | catalogued as COSV53658784; called by muse, mutect2, varscan2
- NUTM2G | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63617235; called by muse, mutect2, varscan2
- NWD1 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV60342050; called by muse, mutect2, varscan2
- OBSCN | c.12653G>T p.R4218L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.6); catalogued as COSV52771928, COSV52780452; called by muse, mutect2, varscan2
- OPN5 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV55245431, COSV99789857; called by muse, mutect2, varscan2
- OR10G9 | c.823T>A p.Y275N | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.9); catalogued as rs775815115, COSV66686218; called by muse, mutect2, varscan2
- OR11L1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV63313700; called by muse, mutect2
- OR14J1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.255); catalogued as COSV65845666; called by muse, mutect2, varscan2
- OR2B3 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV65850912; called by muse, mutect2, varscan2
- OR2G3 | c.59A>T p.H20L | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV60681612, COSV60682420; called by muse, mutect2, varscan2
- OR2L13 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV63552555; called by muse, mutect2, varscan2
- OR2S2 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV59529973; called by muse, mutect2, varscan2
- OR2S2 | c.207C>G p.F69L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV59529991, COSV59531598; called by muse, mutect2, varscan2
- OR2T10 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.196); catalogued as COSV100393702, COSV57896771; called by muse, mutect2, varscan2
- OR4P4 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100111601, COSV58921907; called by muse, mutect2, varscan2
- OR4S2 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV56746721; called by muse, mutect2, varscan2
- OR52N4 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs917264333, COSV57890525, COSV57891018; called by muse, mutect2
- OR5AN1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV58322069; called by muse, mutect2, varscan2
- OR5T3 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57379806; called by muse, mutect2, varscan2
- OR6F1 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV57467703; called by muse, mutect2, varscan2
- OR6K3 | c.250T>A p.F84I (on ENST00000368146; = p.F68I on NM_001005327.2) | Missense Mutation (SNP) | VAF 60/513 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV63745593; called by muse, mutect2, varscan2
- OR6Q1 | c.665A>T p.Y222F | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529254367, COSV56933000; called by muse, mutect2, varscan2
- OR6S1 | c.427T>G p.C143G | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57838112; called by muse, mutect2, varscan2
- OR8H1 | c.737G>C p.G246A | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV57294013, COSV57294876; called by muse, mutect2, varscan2
- OR8H2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs138370909, COSV100542362; called by muse, mutect2, varscan2
- OSBP | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV55662520; called by muse, varscan2
- OSBP2 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV60242510; called by muse, mutect2, varscan2
- OSBPL1A | c.483C>T p.L161= | Splice Region (SNP) | VAF 19/101 reads (19%) | catalogued as COSV60198121; called by muse, mutect2, varscan2
- OTUD4 | c.627C>G p.C209W (on ENST00000447906 / NM_001366057.1; = p.C144W on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.808); catalogued as COSV56850523; called by muse, mutect2, varscan2
- PABPC1L | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53840364; called by muse, mutect2, varscan2
- PADI1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64938339; called by muse, mutect2, varscan2
- PADI3 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.21); catalogued as COSV100968586; called by muse, mutect2, varscan2
- PARD3 | c.2706G>C p.L902F | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV60749704; called by muse, mutect2, varscan2
- PAX8 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV54508359; called by muse, mutect2, varscan2
- PCDHA9 | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65326288; called by muse, mutect2, varscan2
- PCDHB6 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 23/206 reads (11%) | catalogued as COSV50696693; called by muse, mutect2, varscan2
- PCDHB7 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.515); catalogued as rs1554280045, COSV50766294; called by muse, mutect2, varscan2
- PCGF6 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV61495042; called by muse, varscan2
- PCNX1 | c.1904C>G p.S635C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53094251; called by muse, mutect2, varscan2
- PDE7B | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV57496773; called by muse, varscan2
- PDHA1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs794727621, COSV63328091; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PDHA2 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54779068; called by muse, mutect2, varscan2
- PDS5A | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV57825605; called by muse, mutect2, varscan2
- PEG3 | c.4462G>A p.E1488K | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV55632806; called by muse, mutect2
- PEX1 | c.3431C>G p.S1144C | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV50398157; called by muse, mutect2, varscan2
- PEX13 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54369941; called by muse, mutect2, varscan2
- PEX5L | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 22/158 reads (14%) | catalogued as COSV99829797, COSV99829894; called by muse, varscan2
- PGAM2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs781204477, COSV51977805; called by muse, mutect2, varscan2
- PGAP4 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66387624; called by muse, mutect2, varscan2
- PHF20L1 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV55192210; called by muse, mutect2
- PHF3 | c.4514C>G p.S1505* | Nonsense Mutation (SNP) | VAF 26/172 reads (15%) | catalogued as COSV50318281, COSV99029760; called by muse, mutect2, varscan2
- PHIP | c.5046C>G p.I1682M | Missense Mutation (SNP) | VAF 19/596 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV51504268; called by muse, mutect2
- PHRF1 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV52755417; called by muse, mutect2, varscan2
- PIAS3 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV65171339; called by muse, mutect2
- PIK3CB | c.2037-1G>T p.X679_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as COSV56685895; called by muse, mutect2, varscan2
- PIK3CG | c.153C>G p.C51W | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV63248261; called by muse, mutect2, varscan2
- PIK3R1 | c.1880G>C p.G627A (on ENST00000521381 / NM_181523.3; = p.G357A on NM_181504.4) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV57129924; called by muse, mutect2, varscan2
- PIKFYVE | c.4565C>G p.S1522* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | catalogued as COSV52240744; called by muse, mutect2, varscan2
- PIWIL3 | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59995307; called by muse, mutect2, varscan2
- PJVK | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100359434, COSV57868685; called by muse, mutect2
- PKHD1L1 | c.1328G>T p.S443I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.178); catalogued as COSV65742618; called by muse, mutect2, varscan2
- PKP2 | c.2610C>A p.S870R | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV50730315; called by muse, mutect2, varscan2
- PKP4 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); catalogued as rs776377978, COSV67676997, COSV67677234; called by muse, mutect2
- PKP4 | c.3365A>G p.N1122S | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61578647; called by muse, mutect2, varscan2
- PLA2R1 | c.2222G>C p.R741T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206713196, COSV51778384; called by muse, mutect2, varscan2
- PLCH2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53942659; called by muse, mutect2, varscan2
- PLCZ1 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV56852438; called by muse, mutect2, varscan2
- PLEKHG4 | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64612675; called by muse, mutect2, varscan2
- PLEKHH3 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53188891; called by muse, mutect2, varscan2
- PLEKHM1 | c.2047G>C p.D683H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69598849; called by muse, mutect2, varscan2
- PLOD3 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56182879; called by muse, mutect2, varscan2
- PNN | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as COSV53766482; called by muse, mutect2, varscan2
- POLR3D | c.406C>G p.H136D | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs773430316, COSV60571123; called by muse, mutect2, varscan2
- POTEF | c.2158G>T p.G720C | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100665301; called by muse, mutect2, varscan2
- PPP1R15B | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 222/571 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV65815733, COSV65816139; called by muse, mutect2, varscan2
- PPP1R26 | c.495del p.A166Qfs*51 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as COSV100778173; called by mutect2, pindel, varscan2
- PPP2R1A | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59044174; called by muse, mutect2, varscan2
- PPP2R3A | c.884A>T p.E295V | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53863501; called by muse, mutect2, varscan2
- PPP2R5A | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1175746482, COSV54815530; called by muse, mutect2
- PPP6R2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 75/525 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs769883291, COSV53293195, COSV99324087; called by muse, mutect2, varscan2
- PRDM13 | c.2038A>G p.K680E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.994); catalogued as COSV65029660; called by muse, varscan2
- PREPL | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.143); catalogued as COSV53216530; called by muse, mutect2, varscan2
- PRKACB | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1371143203, COSV65762734, COSV65762951; called by muse, mutect2, varscan2
- PRKAG2 | c.1049G>T p.R350M | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55228819; called by muse, mutect2, varscan2
- PRKAG2 | c.755-1G>C p.X252_splice | Splice Site (SNP) | VAF 22/118 reads (19%) | catalogued as COSV55228833; called by muse, mutect2, varscan2
- PRKCQ | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54110762; called by muse, mutect2, varscan2
- PRMT3 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs931915534, COSV58176925; called by muse, mutect2, varscan2
- PRMT3 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58176936; called by muse, mutect2, varscan2
- PRMT5 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as COSV53546080, COSV53547732, COSV99363037; called by muse, mutect2
- PRPF40A | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs548321568, COSV62957474; called by muse, mutect2, varscan2
- PRPSAP2 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52065629, COSV52066466; called by muse, mutect2, varscan2
- PRRC2A | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65686419; called by muse, mutect2
- PRRC2C | c.701G>C p.G234A (on ENST00000367742; = p.G232A on NM_015172.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58905072; called by muse, mutect2, varscan2
- PRSS16 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57915446; called by muse, mutect2, varscan2
- PRSS36 | c.2516C>A p.S839Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV51637130; called by muse, mutect2, varscan2
- PRTFDC1 | c.78G>C p.L26F | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV60774509, COSV60774950; called by muse, mutect2, varscan2
- PSD3 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54070900; called by muse, mutect2, varscan2
- PSMD14 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.745); catalogued as COSV68832405; called by muse, mutect2, varscan2
- PSME2 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1419762547, COSV53756630; called by muse, mutect2, varscan2
- PTCD1 | c.1432A>G p.M478V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868292144, COSV52863330; called by muse, mutect2, varscan2
- PTGR2 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50865758; called by muse, mutect2
- PTK2 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61785400; called by muse, mutect2, varscan2
- PTPN5 | c.1071C>A p.N357K | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62125806; called by muse, mutect2, varscan2
- PTPRK | c.3404A>G p.H1135R (on ENST00000368215 / NM_001291984.2; = p.H1136R on NM_002844.4) | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63897147; called by muse, mutect2, varscan2
- PTPRT | c.1969A>T p.S657C | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV61979999, COSV62004494; called by muse, mutect2, varscan2
- PTPRU | c.2923A>G p.M975V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV60527453; called by muse, mutect2, varscan2
- PTPRZ1 | c.4433C>T p.S1478F | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV66436084; called by muse, mutect2, varscan2
- PUS7L | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV61261815; called by muse, mutect2, varscan2
- PXK | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV57088879; called by muse, mutect2, varscan2
- PXN | c.1239C>G p.F413L (on ENST00000228307 / NM_001080855.3; = p.F379L on NM_002859.4) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57218667; called by muse, varscan2
- RAB11FIP3 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV51933268; called by muse, mutect2, varscan2
- RAB4B | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV54571325; called by muse, mutect2
- RAB6B | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 68/498 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs373337169; called by muse, mutect2, varscan2
- RABGAP1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV65393239; called by muse, mutect2, varscan2
- RABL6 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); catalogued as COSV61035528; called by muse, mutect2, varscan2
- RAD18 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 11/159 reads (7%) | catalogued as COSV53750373; called by muse, mutect2
- RASAL3 | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV52993396; called by muse, mutect2
- RASSF7 | c.290C>G p.S97* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV60347026, COSV60348788; called by muse, mutect2
- RASSF8 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51453486; called by muse, mutect2, varscan2
- RBL1 | c.2266C>A p.H756N | Missense Mutation (SNP) | VAF 71/527 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60329832; called by muse, mutect2, varscan2
- RBM12 | c.2608G>C p.D870H | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58291218; called by muse, mutect2, varscan2
- RBM39 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53615214, COSV53616264, COSV99488189; called by muse, mutect2, varscan2
- RBM47 | c.1142G>C p.R381P | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV55934734, COSV99920950; called by muse, mutect2, varscan2
- RERG | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.66); catalogued as COSV57000887, COSV57001113; called by muse, mutect2, varscan2
- REST | c.2291A>T p.E764V | Missense Mutation (SNP) | VAF 250/667 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV58360563; called by muse, mutect2, varscan2
- RGS13 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67345821; called by muse, mutect2, varscan2
- RHBDD3 | c.624C>G p.C208W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV53323351; called by muse, mutect2, varscan2
- RHNO1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63485325; called by muse, mutect2
- RHOU | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64208600; called by muse, mutect2
- RIC8B | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV62694432; called by muse, mutect2, varscan2
- RIMBP2 | c.1139T>A p.L380Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55471790; called by muse, mutect2, varscan2
- RIPOR2 | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52421145, COSV52428993; called by muse, mutect2, varscan2
- RNASE3 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58959445; called by muse, mutect2, varscan2
- RNF157 | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.293); catalogued as COSV53943981; called by muse, mutect2, varscan2
- RNF185 | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.38); catalogued as COSV56735524; called by muse, mutect2, varscan2
- RNF208 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV61287665; called by muse, mutect2, varscan2
- RNF213 | c.2140C>G p.Q714E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.366); catalogued as COSV60623457; called by muse, mutect2, varscan2
- RNF8 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57720804, COSV57721216; called by muse, mutect2
- ROBO4 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); catalogued as COSV60623764; called by muse, mutect2, varscan2
- RPGR | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58835029; called by muse, mutect2, varscan2
- RPL4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as COSV57179739; called by muse, mutect2, varscan2
- RRNAD1 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV63928962; called by muse, mutect2, varscan2
- RTP5 | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV58319954; called by muse, mutect2, varscan2
- RUFY1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs1180191190, COSV60158305; called by muse, mutect2, varscan2
- RUNX1T1 | c.1471G>A p.A491T (on ENST00000265814 / NM_001198628.1; = p.A464T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs756883632, COSV56146029; called by muse, mutect2, varscan2
- RYR1 | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62096619; called by muse, mutect2, varscan2
- RYR1 | c.7537G>T p.E2513* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV62096625, COSV62112465; called by muse, mutect2, varscan2
- RYR2 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV63667488, COSV63684165; called by muse, mutect2, varscan2
- RYR2 | c.9455G>T p.R3152L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs1307141068, COSV63684182; called by muse, mutect2, varscan2
- SACS | c.5990C>G p.S1997C | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66539551; called by muse, mutect2, varscan2
- SALL1 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV51757133; called by muse, mutect2, varscan2
- SAMD9L | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 129/449 reads (29%) | catalogued as COSV59081382; called by muse, mutect2, varscan2
- SAMD9L | c.3112C>G p.L1038V | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV59081390; called by muse, mutect2, varscan2
- SATB1 | c.2244G>C p.E748D | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV58669313; called by muse, mutect2, varscan2
- SBNO1 | c.2521C>T p.L841F (on ENST00000420886; = p.L840F on NM_018183.5) | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV57341506; called by muse, mutect2, varscan2
- SBSPON | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52076489, COSV99817802; called by muse, mutect2, varscan2
- SELP | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.735); catalogued as COSV55251652; called by muse, mutect2, varscan2
- SEMA3C | c.1832G>T p.R611M | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54846052; called by muse, mutect2, varscan2
- SERHL2 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59668959; called by muse, mutect2
- SERPINB9 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV66233361; called by muse, mutect2, varscan2
- SETD3 | c.1512G>C p.E504D | Missense Mutation (SNP) | VAF 84/493 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV59284242, COSV59284743; called by muse, mutect2, varscan2
- SGK1 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV52805684, COSV52808137; called by muse, mutect2, varscan2
- SH2D3A | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 97/452 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV55585919; called by muse, mutect2, varscan2
- SH3PXD2B | c.2492A>G p.K831R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV61126746; called by muse, mutect2, varscan2
- SHANK2 | c.2956G>C p.E986Q | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV53597031; called by muse, mutect2, varscan2
- SIGLEC8 | c.1266G>T p.W422C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV58472074, COSV58473656; called by muse, mutect2, varscan2
- SIRPA | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV61538411; called by muse, mutect2, varscan2
- SIX4 | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as rs1361457332, COSV53668486, COSV53669981; called by muse, mutect2, varscan2
- SKP2 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 161/523 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV57041899, COSV57042117; called by muse, mutect2, varscan2
- SLC16A4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.505); catalogued as COSV63916524; called by muse, mutect2, varscan2
- SLC22A25 | c.1146G>C p.Q382H | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60595840; called by muse, mutect2, varscan2
- SLC26A4 | c.525G>C p.M175I | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55914806, COSV55916478; called by muse, mutect2
- SLC28A1 | c.1581+1G>A p.X527_splice | Splice Site (SNP) | VAF 63/165 reads (38%) | catalogued as rs763585378, COSV54478896; called by muse, mutect2, varscan2
- SLC2A13 | c.1467C>G p.F489L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55117000; called by muse, mutect2
- SLC35F1 | c.1137C>G p.D379E | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV64502860; called by muse, mutect2, varscan2
- SLC35G1 | c.223A>C p.T75P (on ENST00000427197 / NM_001134658.3; = p.T74P on NM_153226.4) | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV65055300; called by muse, mutect2, varscan2
- SLC39A14 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51484023; called by muse, mutect2
- SLC3A2 | c.958T>C p.S320P | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV58603427; called by muse, mutect2, varscan2
- SLC4A2 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV59656970; called by muse, mutect2, varscan2
- SLC4A7 | c.3524del p.G1175Efs*11 | Frame Shift Del (DEL) | VAF 62/191 reads (32%) | catalogued as rs1184284793; called by mutect2, pindel, varscan2
- SLC4A7 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55397233; called by muse, mutect2, varscan2
- SLC4A7 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs144006432; called by muse, mutect2, varscan2
- SLC5A11 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV61741476, COSV61741483; called by muse, mutect2, varscan2
- SLC7A14 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV51581662; called by muse, mutect2, varscan2
- SLCO2B1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs1427379225, COSV56935005; called by muse, mutect2, varscan2
- SLCO5A1 | c.2020C>A p.L674I | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV52658987; called by muse, mutect2, varscan2
- SLURP1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.933); catalogued as COSV55816085; called by muse, mutect2, varscan2
- SMC4 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61003348, COSV61004740; called by muse, mutect2, varscan2
- SMC6 | c.1248A>T p.R416S | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV61174121; called by muse, mutect2, varscan2
- SMPD1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs570353618, COSV100192681, COSV54967930; called by muse, mutect2, varscan2
- SMTNL1 | c.344A>T p.K115I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67699744; called by muse, mutect2, varscan2
- SNAI2 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50078782, COSV50079014; called by muse, mutect2, varscan2
- SNAPC4 | c.3904C>T p.P1302S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV53730533; called by muse, mutect2, varscan2
- SNED1 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV60023959, COSV60027739; called by muse, mutect2
- SNX13 | c.2686G>C p.E896Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV101296880; called by muse, mutect2, varscan2
- SOCS4 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59460611; called by muse, mutect2, varscan2
- SOCS4 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV59460620; called by muse, mutect2, varscan2
- SORCS1 | c.2189+1G>C p.X730_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | catalogued as COSV53864484; called by muse, mutect2, varscan2
- SPECC1L | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV58658307; called by muse, mutect2, varscan2
- SPEM1 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs768831098, COSV57210134; called by muse, mutect2, varscan2
- SPG11 | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1168881411, COSV55994737; called by muse, mutect2, varscan2
- SPHKAP | c.2596A>T p.S866C | Missense Mutation (SNP) | VAF 322/2035 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.436); catalogued as COSV60877851; called by muse, mutect2, varscan2
- SPICE1 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV55620351, COSV55624417; called by muse, mutect2
- SPINT1 | c.1123G>C p.G375R (on ENST00000344051 / NM_181642.3; = p.G359R on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV59801859; called by muse, mutect2, varscan2
- SPON1 | c.1208T>G p.V403G | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59960786; called by muse, mutect2, varscan2
- SPOPL | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV54513325; called by muse, mutect2, varscan2
- SPTA1 | c.7222G>A p.D2408N | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV63524746; called by muse, mutect2
- SPTA1 | c.4677C>G p.I1559M | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV63751319, COSV63752708; called by muse, mutect2, varscan2
- SPTA1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs372937123, COSV63757170; called by muse, mutect2
- SPTBN4 | c.5520C>G p.F1840L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV58948975; called by muse, mutect2, varscan2
- SRF | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54838497; called by muse, mutect2, varscan2
- SRSF7 | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV57447068; called by muse, mutect2, varscan2
- SS18 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV52260494; called by muse, mutect2, varscan2
- SSH3 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.053); catalogued as COSV57384737; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 30/211 reads (14%) | PolyPhen probably damaging (0.997); catalogued as COSV59565046; called by muse, mutect2, varscan2
- STAB2 | c.5852G>A p.C1951Y | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV66338684; called by muse, mutect2, varscan2
- STAT6 | c.2454G>C p.L818F | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV55666234; called by muse, mutect2, varscan2
- STIP1 | c.557A>T p.D186V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV59439140; called by muse, mutect2, varscan2
- STK10 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV51573844; called by muse, mutect2, varscan2
- STK16 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs548466076, COSV50277899; called by muse, mutect2, varscan2
- STOX2 | c.2491G>C p.D831H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV57851917, COSV57851928; called by muse, mutect2, varscan2
- STT3A | c.1495A>G p.R499G | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV67064698; called by muse, mutect2, varscan2
- STYXL2 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54804862; called by muse, mutect2, varscan2
- SV2B | c.1701G>C p.K567N | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV57699648; called by muse, mutect2
- SVEP1 | c.1318C>T p.H440Y | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV57035650; called by muse, mutect2
- SYDE2 | c.3209C>G p.S1070* | Nonsense Mutation (SNP) | VAF 12/397 reads (3%) | catalogued as COSV58322840; called by muse, mutect2
- SYNE1 | c.22514T>G p.F7505C (on ENST00000367255 / NM_182961.4; = p.F7434C on NM_033071.3) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54975321; called by muse, mutect2, varscan2
432 further variants in this file (167 protein-altering or splice-affecting, 242 silent, 23 other) are not listed here.
